MMRF case MMRF_1184 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/02e02ba3-39e8-4c62-ae9f-25fe5c9d44c1

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 71.2 years (25,990 days); ISS stage: II; Days to last known disease status: 1,632 days (4.5 years); Days to last follow up: 1,632 days (4.5 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 199 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 161 days; Days to treatment end: 161 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 295 days; Days to treatment end: 546 days (1.5 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 547 days (1.5 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -4 (ECOG 1): M Protein 3.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.57 mg/dL; Immunoglobulin G 2.11 g/L; Immunoglobulin A 33.1 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 4.5 µg/mL; Hemoglobin 6.82 mmol/L; Leukocytes 4.97 ×10⁹/L; Absolute Neutrophil 3.49 ×10⁹/L; Platelets 344 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.38 mmol/L; Albumin 36 g/L; Total Protein 9.7 g/dL; Glucose 5.23 mmol/L.
- Day 85 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 2.83 g/L; Immunoglobulin A 4.96 g/L; Immunoglobulin M 0.43 g/L; Hemoglobin 8.62 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 3.08 ×10⁹/L; Platelets 314 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 4.4 mmol/L.
- Day 181 (ECOG 0): Hemoglobin 7.63 mmol/L; Leukocytes 10.8 ×10⁹/L; Platelets 317 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 5.06 mmol/L.
- Day 253 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.869 mg/dL; Immunoglobulin G 6.28 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.37 g/L; Beta 2 Microglobulin 1.9 µg/mL; Lactate Dehydrogenase 7.7 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 5.72 ×10⁹/L; Absolute Neutrophil 2.79 ×10⁹/L; Platelets 320 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.48 mmol/L; Albumin 44 g/L; Total Protein 6.8 g/dL; Glucose 4.13 mmol/L.
- Day 330 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.893 mg/dL; Immunoglobulin G 4.74 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.4 g/L; Hemoglobin 8.74 mmol/L; Leukocytes 4.69 ×10⁹/L; Absolute Neutrophil 2.26 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.45 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 4.29 mmol/L.
- Day 458 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.62 mg/dL; Immunoglobulin G 7.81 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.28 g/L; Hemoglobin 8.74 mmol/L; Leukocytes 4.53 ×10⁹/L; Absolute Neutrophil 2.07 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 3.69 mmol/L.
- Day 547 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.94 mg/dL; Immunoglobulin G 7.36 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.45 ×10⁹/L; Absolute Neutrophil 1.37 ×10⁹/L; Platelets 116 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.15 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 4.02 mmol/L.
- Day 624 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.57 mg/dL; Immunoglobulin G 8.33 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.4 g/L; Hemoglobin 8.68 mmol/L; Leukocytes 6.55 ×10⁹/L; Absolute Neutrophil 3.97 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 4.29 mmol/L.
- Day 727 (ECOG 0): Hemoglobin 8.49 mmol/L; Leukocytes 4.89 ×10⁹/L; Absolute Neutrophil 2.64 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 6.6 g/dL; Glucose 4.46 mmol/L.
- Day 820 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.89 mg/dL; Immunoglobulin G 7.83 g/L; Immunoglobulin A 1.03 g/L; Immunoglobulin M 0.32 g/L; Hemoglobin 8.56 mmol/L; Leukocytes 3.65 ×10⁹/L; Absolute Neutrophil 1.51 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 6.4 g/dL; Glucose 3.96 mmol/L.
- Day 911 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.87 mg/dL; Immunoglobulin G 7.8 g/L; Immunoglobulin A 1.3 g/L; Immunoglobulin M 0.3 g/L; Hemoglobin 7.81 mmol/L; Leukocytes 6.55 ×10⁹/L; Absolute Neutrophil 2.84 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.38 mmol/L; Albumin 38 g/L; Total Protein 6.9 g/dL; Glucose 4.73 mmol/L.
- Day 1,000: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.57 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 1.37 g/L; Immunoglobulin M 0.39 g/L; Hemoglobin 8 mmol/L; Leukocytes 4.72 ×10⁹/L; Absolute Neutrophil 1.89 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.38 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 5.01 mmol/L.
- Day 1,086 (ECOG 0): M Protein 0 g/dL; Immunoglobulin G 9.79 g/L; Immunoglobulin A 1.32 g/L; Immunoglobulin M 0.28 g/L; Hemoglobin 8.06 mmol/L; Leukocytes 3.99 ×10⁹/L; Absolute Neutrophil 1.69 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 35 g/L; Total Protein 6.5 g/dL; Glucose 4.35 mmol/L.
- Day 1,177 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.11 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 1.28 g/L; Immunoglobulin M 0.37 g/L; Hemoglobin 8.06 mmol/L; Leukocytes 4.21 ×10⁹/L; Absolute Neutrophil 1.96 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 4.57 mmol/L.
- Day 1,275 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.24 mg/dL; Immunoglobulin G 9.42 g/L; Immunoglobulin A 1.35 g/L; Immunoglobulin M 0.24 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.58 ×10⁹/L; Absolute Neutrophil 2.15 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 6.3 g/dL; Glucose 3.41 mmol/L.
- Day 1,366 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.52 mg/dL; Immunoglobulin G 9.22 g/L; Immunoglobulin A 1.45 g/L; Immunoglobulin M 0.24 g/L; Hemoglobin 8.68 mmol/L; Leukocytes 3.62 ×10⁹/L; Absolute Neutrophil 1.56 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 6.5 g/dL; Glucose 3.96 mmol/L.
- Day 1,541 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.27 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 1.5 g/L; Immunoglobulin M 0.39 g/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.59 ×10⁹/L; Absolute Neutrophil 1.58 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 4.51 mmol/L.
- Day 1,632 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.01 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 1.59 g/L; Immunoglobulin M 0.37 g/L; Hemoglobin 9.05 mmol/L; Leukocytes 3.58 ×10⁹/L; Absolute Neutrophil 1.42 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 7.1 g/dL; Glucose 4.9 mmol/L.

Other clinical attributes
- Day -4: Weight: 51 kg; Height: 165 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.

Biospecimens (2 samples)
- Sample MMRF_1184_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_1184_2_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 624 days (1.7 years).
